TCGA case TCGA-5S-A9Q8 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Holy Cross. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8751429b-4a11-451e-b978-dc9e9db0eb36

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 51.4 years (18,785 days); Year of diagnosis: 2013; Method of diagnosis: Excisional Biopsy; FIGO stage: Stage IIIA; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 313 days.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 5.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Days to treatment start: 33 days; Days to treatment end: 138 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 186 days; Days to treatment end: 202 days; Treatment dose: 2,100 cGy; Treatment outcome: Complete Response; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 33, day 313.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS.
- Timepoint category: Initial Diagnosis; Weight: 86 kg; Height: 162 cm; BMI: 32.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-5S-A9Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 690 mg.
  Slide TCGA-5S-A9Q8-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 3; Percent stromal cells: 5; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-5S-A9Q8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-5S-A9Q8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: open; History colorectal cancer: No; Diabetes diagnosis indicator: Yes; Hypertension diagnosis: No; Pregnancies full term count: 0; History tamoxifen use: Never Used; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; History tamoxifen use: Never Used; Hypertension diagnosis: No; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 0; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 313 days; disease-specific survival: no event (censored), 313 days; disease-free interval: no event (censored), 313 days; progression-free interval: no event (censored), 313 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-5S-A9Q8-01A-11D-A402-01): tumor purity 0.94, ploidy 2.01, whole-genome doublings 0.
